Somatic mutation profile of cancer-model specimen HCM-BROD-0053-C49-85M (Adherent Cell Line, passage 14; aliquot HCM-BROD-0053-C49-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0053-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Tumor grade: G2; Age at diagnosis: 16.0 years (5,851 days).
Specimen HCM-BROD-0053-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b062d77d-c0be-4834-8c15-fc2f3a1c890b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0053-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0053-C49-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b6ae23c-c061-417e-89e8-3eb5ea31dda8

The open-access MAF lists 73 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Frame Shift Del 5, Splice Site 4, Nonsense Mutation 4, Intron 2, Frame Shift Ins 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-10_936del p.X307_splice | Splice Site (DEL) | VAF 85/93 reads (91%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAMTS12 | c.1142del p.D381Vfs*14 | Frame Shift Del (DEL) | VAF 140/322 reads (43%) | catalogued as COSV61255742; called by mutect2, pindel*, varscan2
- ANKRD62 | c.54G>A p.W18* | Nonsense Mutation (SNP) | VAF 101/433 reads (23%) | catalogued as COSV100019010; called by muse, mutect2, varscan2
- EPRS1 | c.933_934del p.H311Qfs*6 | Frame Shift Del (DEL) | VAF 61/144 reads (42%) | catalogued as rs748808852; called by mutect2, pindel, varscan2
- EXOC3L4 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 175/752 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as COSV66295287; called by muse, mutect2, varscan2
- GABRA4 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs1394753567; called by muse, mutect2, varscan2
- GNL3L | c.1093G>C p.A365P | Missense Mutation (SNP) | VAF 351/694 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV60575423; called by muse, mutect2, varscan2
- JPH1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 342/1009 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749838028, COSV60608697; called by muse, mutect2, varscan2
- KIF16B | c.3667C>T p.R1223C | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916333312; called by muse, mutect2, varscan2
- MAP1A | c.7924C>T p.R2642W | Missense Mutation (SNP) | VAF 304/613 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753231605, COSV55809889; called by muse, mutect2, varscan2
- MTPAP | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 195/430 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs1483706598; called by muse, mutect2, varscan2
- OR2L5 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV62365008; called by muse, mutect2, varscan2
- OR5AS1 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs773462317, COSV57982651, COSV57982974; called by muse, mutect2, varscan2
- RFPL4AL1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 164/494 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs750424785; called by muse, varscan2
- STOX1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as rs751546020; called by muse, mutect2, varscan2
- TMC2 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs1299359798; called by muse, mutect2, varscan2
- AFTPH | c.2086G>C p.G696R | Missense Mutation (SNP) | VAF 96/149 reads (64%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- AGO4 | c.1049A>G p.Q350R | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBLB | c.1967C>A p.S656Y | Missense Mutation (SNP) | VAF 94/183 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CFAP221 | c.977T>A p.V326D | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNKSR2 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL13A1 | c.1891G>T p.G631* (on ENST00000398978 / NM_001130103.2; = p.G559* on NM_080798.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 192/384 reads (50%) | called by mutect2, varscan2
- CPA3 | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPT1B | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 217/389 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CR1L | c.1409_1414+39del p.X470_splice | Splice Site (DEL) | VAF 86/360 reads (24%) | called by mutect2, pindel
- ELOA | c.986A>T p.D329V | Missense Mutation (SNP) | VAF 190/394 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GAB1 | c.703T>G p.F235V | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- GREM2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 271/545 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRIN2D | c.1448G>A p.C483Y | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELZ2 | c.6231G>C p.K2077N (on ENST00000467148 / NM_001037335.2; = p.K1508N on NM_033405.3) | Missense Mutation (SNP) | VAF 269/544 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNT2 | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 113/202 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT2D | c.5675A>G p.Q1892R | Missense Mutation (SNP) | VAF 170/440 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- KRT10 | c.640del p.T214Qfs*23 | Frame Shift Del (DEL) | VAF 77/244 reads (32%) | called by mutect2, pindel, varscan2
- MTMR4 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 118/470 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTPAP | c.1512A>T p.E504D | Missense Mutation (SNP) | VAF 134/308 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO1C | c.2282-15_2288del p.X761_splice (on ENST00000648651 / NM_001080779.2; = p.X726_splice on NM_033375.5) | Splice Site (DEL) | VAF 168/217 reads (77%) | called by mutect2, varscan2
- OR4Q2 | c.893del p.K298Sfs*6 | Frame Shift Del (DEL) | VAF 130/228 reads (57%) | called by mutect2, pindel*, varscan2
- OR51G2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 194/436 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX1 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 254/499 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZD2 | c.6946A>T p.R2316* | Nonsense Mutation (SNP) | VAF 146/325 reads (45%) | called by muse, mutect2, varscan2
- PLCG2 | c.1884G>C p.E628D | Missense Mutation (SNP) | VAF 293/690 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLEKHG4B | c.3477C>A p.D1159E (on ENST00000283426; = p.D1515E on NM_052909.5) | Missense Mutation (SNP) | VAF 151/382 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- PLPPR1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/200 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); called by muse, varscan2
- PPEF1 | c.547A>C p.I183L | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RSPO4 | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 167/772 reads (22%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 404/629 reads (64%) | SIFT tolerated (0.56); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC48A1 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 335/657 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- SND1 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 272/590 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- TEP1 | c.7261A>G p.K2421E | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TFB1M | c.657dup p.K220Qfs*51 | Frame Shift Ins (INS) | VAF 102/219 reads (47%) | called by pindel, varscan2
- TTN | c.28931A>C p.K9644T (on ENST00000591111; = p.K8717T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/329 reads (29%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TXLNB | c.1170A>C p.K390N | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- USP9X | c.1756_1763+4del p.X586_splice | Splice Site (DEL) | VAF 43/104 reads (41%) | called by mutect2, pindel, varscan2
- WDR48 | c.2003_2007del p.L668Pfs*46 | Frame Shift Del (DEL) | VAF 208/431 reads (48%) | called by mutect2, pindel, varscan2
- ZNRF3 | c.1501C>A p.P501T (on ENST00000544604 / NM_001206998.2; = p.P401T on NM_032173.3) | Missense Mutation (SNP) | VAF 237/1180 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACAN | c.6387G>A p.L2129= | Silent (SNP) | VAF 193/521 reads (37%) | catalogued as COSV61358543; called by muse, mutect2, varscan2
- ADAM23 | c.1401C>A p.S467= | Silent (SNP) | VAF 82/150 reads (55%) | called by muse, mutect2, varscan2
- AHNAK | c.7320G>A p.K2440= | Silent (SNP) | VAF 194/472 reads (41%) | called by muse, mutect2, varscan2
- CD247 | c.291G>T p.G97= | Silent (SNP) | VAF 83/440 reads (19%) | called by muse, mutect2, varscan2
- CPT1A | c.1131G>A p.E377= | Silent (SNP) | VAF 97/413 reads (23%) | catalogued as rs1215645933, COSV55759035; called by muse, mutect2, varscan2
- CPT1B | c.102T>A p.S34= | Silent (SNP) | VAF 216/384 reads (56%) | called by muse, mutect2, varscan2
- FOXL2NB | c.360C>T p.A120= | Silent (SNP) | VAF 451/949 reads (48%) | called by muse, mutect2, varscan2
- IKZF1 | c.516C>A p.P172= | Silent (SNP) | VAF 114/1020 reads (11%) | catalogued as rs1408237812; called by muse, mutect2, varscan2
- L1TD1 | c.720A>C p.G240= | Silent (SNP) | VAF 163/350 reads (47%) | catalogued as rs1358914167; called by muse, mutect2, varscan2
- MERTK | c.2391A>C p.G797= | Silent (SNP) | VAF 159/293 reads (54%) | called by muse, mutect2, varscan2
- OTP | c.99G>C p.V33= | Silent (SNP) | VAF 355/739 reads (48%) | catalogued as COSV100119936; called by muse, mutect2, varscan2
- PCDHA4 | c.1407G>A p.P469= | Silent (SNP) | VAF 285/621 reads (46%) | called by muse, mutect2, varscan2
- ROR1 | c.1989C>T p.A663= | Silent (SNP) | VAF 65/305 reads (21%) | catalogued as COSV64292138; called by muse, mutect2, varscan2
- SSTR1 | c.411C>T p.D137= | Silent (SNP) | VAF 255/430 reads (59%) | catalogued as COSV99942633; called by muse, mutect2, varscan2
- STEAP3 | c.987C>T p.H329= | Silent (SNP) | VAF 243/425 reads (57%) | called by muse, mutect2, varscan2
- C12orf76 | n.429G>A | RNA (SNP) | VAF 88/364 reads (24%) | called by muse, varscan2
- TOR1AIP2 | c.-147+12125A>G | Intron (SNP) | VAF 85/367 reads (23%) | catalogued as rs754638781; called by muse, mutect2, varscan2
- TUBB3 | c.277+110T>G | Intron (SNP) | VAF 99/456 reads (22%) | called by muse, mutect2, varscan2
